Somatic mutation profile of tumor specimen TCGA-FY-A40N-01A (aliquot TCGA-FY-A40N-01A-11D-A23M-08) from TCGA case TCGA-FY-A40N, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 55.6 years (20,320 days).
Specimen TCGA-FY-A40N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d70b794c-9cd9-472a-ba60-2eb85a14a53d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A40N-10A (Blood Derived Normal), aliquot TCGA-FY-A40N-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b895352-bebe-4cf4-98ea-70dc85f380d5

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUL1 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 32/112 reads (29%) | catalogued as COSV100296692; called by muse, varscan2
- CUL1 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV100296358, COSV100296694; called by muse, varscan2
